Somatic mutation profile of tumor specimen TCGA-CN-A63W-01A (aliquot TCGA-CN-A63W-01A-11D-A30E-08) from TCGA case TCGA-CN-A63W, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 48.4 years (17,693 days).
Specimen TCGA-CN-A63W-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 28c5c999-3e70-4314-9183-1be96ba1430b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CN-A63W-10A (Blood Derived Normal), aliquot TCGA-CN-A63W-10A-01D-A30H-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/829744b6-e742-4b4b-84d1-944daebb59b6

The open-access MAF lists 435 somatic variants for this specimen: 327 protein-altering or splice-affecting, 101 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 284, Silent 101, Nonsense Mutation 19, Frame Shift Del 10, Splice Site 9, RNA 3, Intron 2, Frame Shift Ins 2, Splice Region 2, 3'UTR 1, Nonstop Mutation 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.892G>T p.E298* | Nonsense Mutation (SNP) | VAF 31/46 reads (67%) | hotspot (GDC flag); catalogued as rs201744589, CM031387, COSV52661551, COSV52761493, COSV53353479, COSV53790595; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.9690A>T p.Q3230H | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.698); catalogued as COSV101447175; called by muse, mutect2, varscan2
- ABCA5 | c.3602A>T p.Y1201F | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT tolerated (0.68); PolyPhen benign (0.165); catalogued as COSV101201269; called by muse, mutect2, varscan2
- ADAM20 | c.1619G>T p.R540L | Missense Mutation (SNP) | VAF 43/83 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); catalogued as COSV56455635, COSV99833567; called by muse, mutect2, varscan2
- ADAMTS5 | c.2275A>G p.K759E | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.996); catalogued as COSV99538260; called by muse, mutect2, varscan2
- ADCY1 | c.610C>A p.P204T | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as COSV99812804; called by muse, mutect2, varscan2
- ADCY8 | c.407C>T p.P136L | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.686); catalogued as COSV99654068; called by muse, mutect2, varscan2
- AFF3 | c.2240C>T p.P747L | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100419955; called by muse, mutect2
- AHDC1 | c.2434G>A p.G812S | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT tolerated (0.6); PolyPhen benign (0.039); catalogued as COSV99899703; called by muse, mutect2, varscan2
- AIMP2 | c.520A>G p.K174E | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.87); PolyPhen benign (0.054); catalogued as rs1441116607, COSV99552252; called by muse, mutect2, varscan2
- ALDOC | c.271G>A p.G91S | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs866773840, COSV99257225; called by muse, mutect2, varscan2
- ALKBH1 | c.389A>T p.N130I | Missense Mutation (SNP) | VAF 25/154 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.909); catalogued as COSV99380757; called by muse, mutect2, varscan2
- ANK2 | c.9535G>A p.A3179T | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.015); catalogued as rs527731735, COSV100003892; called by muse, mutect2, varscan2
- ANKLE1 | c.1177G>C p.D393H (on ENST00000394458; = p.D339H on NM_152363.6) | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV100845774; called by muse, mutect2, varscan2
- ANO1 | c.502G>C p.E168Q | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV100304417; called by muse, mutect2, varscan2
- AOAH | c.461G>T p.R154I | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV99333686; called by muse, mutect2, varscan2
- APBA1 | c.1106A>G p.Y369C | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as COSV99597022; called by muse, mutect2, varscan2
- APOB | c.8133C>A p.F2711L | Missense Mutation (SNP) | VAF 42/144 reads (29%) | SIFT tolerated (0.52); PolyPhen benign (0.084); catalogued as COSV99267668; called by muse, mutect2, varscan2
- AREL1 | c.1775G>T p.R592L | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100707646; called by muse, mutect2, varscan2
- ARHGAP26 | c.1722G>A p.M574I | Missense Mutation (SNP) | VAF 97/135 reads (72%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as COSV99191360; called by muse, mutect2, varscan2
- ASB8 | c.403C>T p.R135W | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as rs978834302, COSV56659032; called by muse, mutect2, varscan2
- ATOH1 | c.131G>C p.R44T | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.158); catalogued as COSV100024570; called by muse, mutect2, varscan2
- ATP10A | c.1835G>T p.R612M | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.044); catalogued as COSV100791496; called by muse, mutect2, varscan2
- ATP10D | c.1528G>C p.G510R | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT tolerated (0.77); PolyPhen benign (0.006); catalogued as COSV99906131; called by muse, mutect2, varscan2
- BBS10 | c.970G>T p.G324W | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as COSV99675515; called by muse, mutect2, varscan2
- BCAN | c.344C>T p.A115V | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.828); catalogued as rs757148760, COSV61255311; called by muse, mutect2, varscan2
- BCAS2 | c.621T>G p.Y207* | Nonsense Mutation (SNP) | VAF 36/137 reads (26%) | catalogued as COSV101058662; called by muse, mutect2, varscan2
- BIRC7 | c.873C>G p.S291R (on ENST00000217169 / NM_139317.3; = p.S273R on NM_022161.4) | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.062); catalogued as COSV99416977; called by muse, mutect2
- BOLL | c.728A>C p.E243A | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.637); catalogued as COSV99987380; called by muse, mutect2, varscan2
- BSX | c.701G>T p.*234Lext*? | Nonstop Mutation (SNP) | VAF 13/46 reads (28%) | catalogued as COSV100545324; called by muse, mutect2, varscan2
- BTNL2 | c.497C>A p.A166E | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.534); catalogued as COSV100896193; called by muse, mutect2, varscan2
- C1orf112 | c.296C>G p.T99R | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV99610141; called by muse, mutect2, varscan2
- C3orf56 | c.529G>T p.A177S | Missense Mutation (SNP) | VAF 29/38 reads (76%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.601); catalogued as COSV101228982; called by muse, mutect2, varscan2
- C4orf50 | c.617C>G p.T206R (on ENST00000324058; = p.T1438R on NM_001364689.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.5); PolyPhen benign (0.122); catalogued as COSV100136147, COSV60691453; called by muse, mutect2, varscan2
- CA8 | c.589A>G p.T197A | Missense Mutation (SNP) | VAF 36/133 reads (27%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as COSV100527270; called by muse, mutect2, varscan2
- CACNA1B | c.6716T>A p.L2239Q | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.926); catalogued as rs1468256173, COSV99499459; called by muse, mutect2, varscan2
- CALCA | c.347C>A p.P116H | Missense Mutation (SNP) | VAF 35/92 reads (38%) | SIFT tolerated (0.54); PolyPhen benign (0.42); catalogued as COSV100524105; called by muse, mutect2, varscan2
- CAPRIN2 | c.1659G>C p.E553D | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.496); catalogued as COSV99195659; called by muse, mutect2
- CAPZA3 | c.234G>T p.M78I | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV99856890; called by muse, mutect2, varscan2
- CASP8AP2 | c.866A>T p.E289V | Missense Mutation (SNP) | VAF 74/172 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99387511; called by muse, mutect2, varscan2
- CC2D1A | c.503G>T p.R168L | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100528683, COSV58786237; called by muse, mutect2, varscan2
- CCDC50 | c.55C>G p.R19G | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV66667646; called by muse, mutect2, varscan2
- CCDC54 | c.818A>C p.Q273P | Missense Mutation (SNP) | VAF 37/53 reads (70%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV99660324; called by muse, mutect2, varscan2
- CCDC88C | c.323G>T p.G108V | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV101106124; called by muse, mutect2, varscan2
- CDADC1 | c.177+1G>T p.X59_splice | Splice Site (SNP) | VAF 36/60 reads (60%) | catalogued as rs1477763968, COSV99212606; called by muse, mutect2, varscan2
- CDC42BPG | c.1549G>A p.G517R | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.37); PolyPhen benign (0.058); catalogued as COSV100712148; called by muse, mutect2, varscan2
- CDH22 | c.957G>T p.E319D | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.761); catalogued as COSV100952975; called by muse, mutect2, varscan2
- CDH8 | c.340G>T p.V114L | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs1567520353, COSV100183923; called by muse, mutect2, varscan2
- CEMP1 | c.76C>G p.L26V | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.801); catalogued as COSV99566116; called by muse, mutect2
- CEP250 | c.3899-1G>C p.X1300_splice | Splice Site (SNP) | VAF 7/14 reads (50%) | catalogued as COSV100699154; called by muse, mutect2, varscan2
- CFAP47 | c.4583A>G p.K1528R | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.044); catalogued as rs774144313, COSV100545686; called by muse, mutect2, varscan2
- CFAP91 | c.2092G>A p.V698I | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs193146105, COSV56346419; called by muse, mutect2, varscan2
- CFH | c.418A>T p.I140L | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.82); PolyPhen benign (0.007); catalogued as COSV100661619, COSV62776380; called by muse, mutect2, varscan2
- CFHR1 | c.343A>G p.N115D | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.482); catalogued as COSV100258967; called by muse, mutect2, varscan2
- CHST2 | c.1200T>A p.N400K | Missense Mutation (SNP) | VAF 46/89 reads (52%) | SIFT tolerated (0.74); PolyPhen benign (0.131); catalogued as COSV100536111; called by muse, mutect2, varscan2
- CHST6 | c.1031G>A p.R344H | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.908); catalogued as COSV100178344; called by muse, mutect2, varscan2
- CLCN5 | c.2018C>G p.T673S | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100260367; called by muse, mutect2, varscan2
- CLEC4D | c.130C>A p.H44N | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT deleterious (0.02); PolyPhen benign (0.145); catalogued as COSV100223137, COSV55228624; called by muse, mutect2, varscan2
- CMIP | c.1076G>T p.C359F (on ENST00000537098 / NM_198390.2; = p.C265F on NM_030629.3) | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.974); catalogued as COSV101220957; called by muse, mutect2, varscan2
- CNTNAP5 | c.661G>A p.G221R | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT tolerated (0.64); PolyPhen probably damaging (1); catalogued as COSV101444152; called by muse, mutect2, varscan2
- CNTNAP5 | c.2534C>A p.P845H | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV101444153; called by muse, mutect2, varscan2
- COL11A1 | c.3959C>T p.P1320L | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as COSV100617923; called by muse, mutect2, varscan2
- COL11A1 | c.3655G>T p.G1219W | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100617924; called by muse, mutect2, varscan2
- COL1A1 | c.3398G>A p.G1133E | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99868027; called by muse, mutect2, varscan2
- COL3A1 | c.2809G>T p.A937S | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV58597000; called by muse, mutect2, varscan2
- COL8A1 | c.622G>C p.G208R | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); catalogued as COSV99658363; called by muse, mutect2, varscan2
- COQ5 | c.671A>G p.H224R | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.139); catalogued as COSV99942498; called by muse, mutect2, varscan2
- CORO2A | c.145G>T p.A49S | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1276555719, COSV100674112; called by muse, mutect2
- CPEB4 | c.1129C>G p.R377G | Missense Mutation (SNP) | VAF 54/84 reads (64%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.754); catalogued as COSV54176628, COSV99437608; called by muse, mutect2, varscan2
- CPO | c.100G>C p.D34H | Missense Mutation (SNP) | VAF 24/38 reads (63%) | SIFT deleterious (0); PolyPhen benign (0.346); catalogued as COSV99786634; called by muse, mutect2, varscan2
- CPZ | c.206C>A p.S69* (on ENST00000360986 / NM_001014447.3; = p.S58* on NM_003652.3) | Nonsense Mutation (SNP) | VAF 9/47 reads (19%) | catalogued as rs773719320, COSV100249238; called by muse, mutect2, varscan2
- CRB1 | c.2078G>A p.S693N | Missense Mutation (SNP) | VAF 26/47 reads (55%) | SIFT tolerated (0.36); PolyPhen benign (0.006); catalogued as COSV100958065; called by muse, mutect2, varscan2
- CRISP1 | c.148G>A p.A50T | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs753227426, COSV59995189; called by muse, mutect2, varscan2
- CSF2RB | c.2255C>A p.P752H | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.042); catalogued as COSV99454361; called by muse, mutect2, varscan2
- CSMD3 | c.2905C>T p.Q969* (on ENST00000297405 / NM_001363185.1; = p.Q865* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 14/60 reads (23%) | catalogued as COSV99846166; called by muse, mutect2, varscan2
- CSN2 | c.574C>T p.P192S | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.713); catalogued as rs1484916164, COSV100778826; called by muse, mutect2, varscan2
- CSPG4 | c.6365G>C p.R2122T | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.348); catalogued as COSV100414116; called by muse, mutect2
- CSRNP3 | c.568G>T p.G190* | Nonsense Mutation (SNP) | VAF 74/191 reads (39%) | catalogued as COSV100086246; called by muse, mutect2, varscan2
- CUBN | c.2495T>A p.F832Y | Missense Mutation (SNP) | VAF 32/44 reads (73%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV100913438; called by muse, mutect2, varscan2
- CYTIP | c.904A>G p.N302D | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.22); catalogued as COSV99938907; called by muse, mutect2, varscan2
- DCDC2B | c.647C>A p.P216H | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.03); catalogued as COSV99356780; called by muse, mutect2, varscan2
- DCTN1 | c.712C>T p.R238W | Missense Mutation (SNP) | VAF 181/443 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV62619770; called by muse, mutect2, varscan2
- DGKB | c.1937G>T p.G646V | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99342987; called by muse, mutect2
- DHX8 | c.1624G>T p.A542S | Missense Mutation (SNP) | VAF 65/181 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as COSV99292587; called by muse, mutect2, varscan2
- DIP2C | c.4565T>A p.I1522N | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.09); catalogued as COSV99793555; called by muse, mutect2, varscan2
- DLGAP3 | c.701A>C p.H234P | Missense Mutation (SNP) | VAF 46/81 reads (57%) | SIFT deleterious (0.02); PolyPhen benign (0.106); catalogued as COSV99333129; called by muse, mutect2, varscan2
- DMBT1 | c.6604A>T p.S2202C (on ENST00000338354 / NM_001377530.1; = p.S1445C on NM_004406.3) | Missense Mutation (SNP) | VAF 26/36 reads (72%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.894); catalogued as COSV100353998; called by muse, mutect2, varscan2
- DMD | c.4217T>G p.M1406R | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); catalogued as COSV100822372; called by muse, mutect2, varscan2
- DMD | c.2179G>T p.D727Y | Missense Mutation (SNP) | VAF 14/20 reads (70%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV55882246, COSV99918704, COSV99925621; called by muse, mutect2, varscan2
- DNAH5 | c.10695G>T p.E3565D | Missense Mutation (SNP) | VAF 39/144 reads (27%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV99453531; called by muse, mutect2, varscan2
- DNAH5 | c.9350G>T p.W3117L | Missense Mutation (SNP) | VAF 106/192 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54211920; called by muse, mutect2, varscan2
- DNAJC2 | c.1542del p.D515Mfs*3 | Frame Shift Del (DEL) | VAF 12/25 reads (48%) | catalogued as COSV50786823; called by mutect2, pindel, varscan2
- DNM3 | c.2546G>A p.R849K (on ENST00000355305 / NM_001350206.2; = p.R843K on NM_015569.5) | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT tolerated, low confidence (0.31); PolyPhen possibly damaging (0.745); catalogued as COSV100798623; called by muse, mutect2, varscan2
- DOCK8 | c.235C>T p.L79F | Missense Mutation (SNP) | VAF 17/23 reads (74%) | SIFT tolerated (0.71); PolyPhen benign (0.014); catalogued as COSV101210344; called by muse, mutect2, varscan2
- DPYSL3 | c.1456A>G p.R486G | Missense Mutation (SNP) | VAF 31/50 reads (62%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV100575352; called by muse, mutect2, varscan2
- DRD2 | c.119T>A p.L40Q | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV100670101; called by muse, mutect2, varscan2
- DSP | c.6733G>C p.E2245Q | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.89); catalogued as COSV101131709; called by muse, mutect2, varscan2
- DTNB | c.1754G>A p.R585H | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as rs774525815, COSV56472741; called by muse, mutect2, varscan2
- DUSP13 | c.65T>C p.L22P | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV100403789; called by muse, mutect2, varscan2
- DYNC1I1 | c.1876G>C p.V626L | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as COSV100269153; called by muse, mutect2, varscan2
- ECE2 | c.42G>T p.M14I | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.964); catalogued as COSV100668827; called by muse, mutect2, varscan2
- EFCAB13 | c.2422+2T>A p.X808_splice | Splice Site (SNP) | VAF 12/33 reads (36%) | catalogued as COSV100516884; called by muse, mutect2, varscan2
- EHD4 | c.1467G>T p.K489N | Missense Mutation (SNP) | VAF 21/34 reads (62%) | SIFT tolerated (0.19); PolyPhen benign (0.031); catalogued as COSV99588310, COSV99588363; called by muse, mutect2, varscan2
- ELAC1 | c.456A>T p.Q152H | Missense Mutation (SNP) | VAF 18/30 reads (60%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.447); catalogued as COSV99495020; called by muse, mutect2, varscan2
- ELL2 | c.1683G>T p.R561S | Missense Mutation (SNP) | VAF 45/67 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); catalogued as COSV52982303; called by muse, mutect2, varscan2
- EP300 | c.3671+1G>T p.X1224_splice | Splice Site (SNP) | VAF 5/29 reads (17%) | catalogued as COSV54327591, COSV99607896; called by muse, mutect2
- EPC2 | c.1612A>T p.S538C | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.615); catalogued as COSV99310138; called by muse, mutect2, varscan2
- EPDR1 | c.493G>C p.G165R | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99554650; called by muse, mutect2, varscan2
- EXPH5 | c.5536A>T p.S1846C | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV99762109; called by muse, mutect2, varscan2
- FA2H | c.486G>T p.E162D | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV99547919; called by muse, mutect2, varscan2
- FBN1 | c.1872G>T p.M624I | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.096); catalogued as COSV100356281; called by muse, mutect2
- FCGRT | c.1068G>T p.K356N | Missense Mutation (SNP) | VAF 55/152 reads (36%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.017); catalogued as COSV54543100; called by muse, mutect2, varscan2
- FGF3 | c.410T>A p.V137E | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT tolerated (0.34); PolyPhen benign (0.207); catalogued as COSV100490297; called by muse, mutect2, varscan2
- FHL5 | c.13C>G p.H5D | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.09); catalogued as COSV100459758; called by muse, mutect2, varscan2
- FMN2 | c.4216-2A>T p.X1406_splice | Splice Site (SNP) | VAF 17/40 reads (43%) | catalogued as COSV100146977; called by muse, mutect2, varscan2
- FMO3 | c.382A>G p.T128A | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs755417548, COSV100882543; called by muse, mutect2, varscan2
- FOXI1 | c.1013C>T p.A338V | Missense Mutation (SNP) | VAF 26/40 reads (65%) | SIFT tolerated (0.31); PolyPhen benign (0.125); catalogued as rs367809742; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FRMD1 | c.242A>G p.Q81R | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.49); PolyPhen benign (0.106); catalogued as rs1466280016, COSV99350094; called by muse, mutect2, varscan2
- GABRA4 | c.868G>T p.V290L | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99974421; called by muse, mutect2, varscan2
- GABRG3 | c.925C>A p.R309S | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100409573, COSV61510788; called by muse, mutect2, varscan2
- GANC | c.289G>C p.E97Q | Missense Mutation (SNP) | VAF 22/49 reads (45%) | PolyPhen benign (0.041); catalogued as COSV100531209; called by muse, mutect2, varscan2
- GNAL | c.804G>A p.W268* (on ENST00000269162 / NM_001142339.3; = p.W345* on NM_182978.4) | Nonsense Mutation (SNP) | VAF 21/103 reads (20%) | catalogued as COSV52332734, COSV99304109; called by muse, mutect2, varscan2
- GOLGB1 | c.8773C>G p.Q2925E | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.062); catalogued as COSV100511469; called by muse, mutect2, varscan2
- GPI | c.283G>T p.G95C | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.744); catalogued as COSV100731568; called by muse, mutect2, varscan2
- GPR1 | c.883C>G p.L295V | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.067); catalogued as COSV101329864, COSV67976394, COSV67977204; called by muse, mutect2, varscan2
- GRIN2A | c.1927G>T p.A643S | Missense Mutation (SNP) | VAF 42/54 reads (78%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV58043725, COSV58051408; called by muse, mutect2, varscan2
- GRM5 | c.1671G>T p.W557C | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100554247; called by muse, mutect2, varscan2
- GRM7 | c.1096G>T p.E366* | Nonsense Mutation (SNP) | VAF 16/28 reads (57%) | catalogued as COSV63159229, COSV63162440; called by muse, mutect2, varscan2
- H1-2 | c.356A>G p.K119R | Missense Mutation (SNP) | VAF 36/110 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.036); catalogued as rs374398098, COSV100642327; called by muse, mutect2, varscan2
- H1-8 | c.1026G>C p.Q342H | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.288); catalogued as COSV100140336; called by muse, mutect2, varscan2
- H2AC17 | c.85G>T p.G29* | Nonsense Mutation (SNP) | VAF 21/48 reads (44%) | catalogued as COSV100377716; called by muse, mutect2, varscan2
- HBD | c.316C>T p.L106F | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53082037; called by muse, mutect2, varscan2
- HCN3 | c.1200A>C p.E400D | Missense Mutation (SNP) | VAF 35/68 reads (51%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as COSV100713023; called by muse, mutect2, varscan2
- HEXD | c.991G>C p.D331H | Missense Mutation (SNP) | VAF 132/274 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.428); catalogued as COSV100027992; called by muse, mutect2, varscan2
- HEXIM1 | c.877G>T p.E293* | Nonsense Mutation (SNP) | VAF 33/85 reads (39%) | catalogued as COSV100203578, COSV60176704; called by muse, mutect2, varscan2
- HMGCLL1 | c.457C>T p.P153S | Missense Mutation (SNP) | VAF 31/62 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99233116, COSV99233408; called by muse, mutect2, varscan2
- HNRNPA3 | c.479A>T p.D160V | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV101182967; called by muse, mutect2, varscan2
- HOXD4 | c.611A>T p.N204I | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100107019; called by muse, mutect2, varscan2
- HPGD | c.487C>T p.R163C | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs181587981, COSV56662870, COSV56663226; called by muse, mutect2, varscan2
- HTR3A | c.1141A>T p.M381L | Missense Mutation (SNP) | VAF 38/124 reads (31%) | SIFT tolerated (0.95); PolyPhen benign (0.003); catalogued as COSV100248603; called by muse, mutect2, varscan2
- IFT81 | c.399G>T p.Q133H | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (0.26); PolyPhen benign (0.143); catalogued as COSV99656346; called by muse, mutect2, varscan2
- IGKV1D-43 | c.349C>T p.P117S | Missense Mutation (SNP) | VAF 73/268 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1553408932; called by muse, mutect2, varscan2
- IKZF3 | c.913G>T p.D305Y | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV99500135; called by muse, mutect2, varscan2
- IL9R | c.636T>A p.F212L | Missense Mutation (SNP) | VAF 16/25 reads (64%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV99730170; called by muse, mutect2, varscan2
- INPP5J | c.1271G>T p.R424L | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.454); catalogued as COSV100459764, COSV58514266; called by muse, mutect2, varscan2
- INTS7 | c.2577G>C p.Q859H | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV100877561; called by muse, mutect2
- ITPR2 | c.8072C>T p.T2691I | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.043); catalogued as COSV101190139; called by muse, mutect2, varscan2
- JMJD1C | c.2642C>T p.S881F | Missense Mutation (SNP) | VAF 30/57 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.439); catalogued as COSV101232467; called by muse, mutect2, varscan2
- KANSL3 | c.1248G>C p.M416I | Missense Mutation (SNP) | VAF 44/117 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.219); catalogued as COSV100831239; called by muse, mutect2, varscan2
- KBTBD12 | c.1563C>A p.N521K | Missense Mutation (SNP) | VAF 7/9 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100675518; called by muse, mutect2, varscan2
- KCNB2 | c.808G>C p.D270H | Missense Mutation (SNP) | VAF 39/111 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101578989, COSV73049233; called by muse, mutect2, varscan2
- KCNK13 | c.983A>G p.E328G | Missense Mutation (SNP) | VAF 35/108 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV99965904; called by muse, mutect2, varscan2
- KCNK6 | c.223G>T p.V75F | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as COSV99649476; called by muse, mutect2, varscan2
- KHDRBS2 | c.846C>G p.D282E | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV55495558, COSV99837055; called by muse, mutect2, varscan2
- KHDRBS2 | c.154G>T p.V52F | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.793); catalogued as COSV99837056; called by muse, mutect2, varscan2
- KIF19 | c.1152G>T p.E384D | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV100739167; called by muse, mutect2, varscan2
- KIR2DL3 | c.715+1G>T p.X239_splice | Splice Site (SNP) | VAF 55/167 reads (33%) | catalogued as COSV100668063; called by muse, mutect2, varscan2
- KRBA1 | c.3085dup p.A1029Gfs*98 | Frame Shift Ins (INS) | VAF 4/10 reads (40%) | catalogued as rs1008481842; called by mutect2, varscan2
- LAMA4 | c.2889G>T p.K963N (on ENST00000230538 / NM_001105206.3; = p.K956N on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.444); catalogued as COSV100039313; called by muse, mutect2, varscan2
- LANCL2 | c.540G>T p.Q180H | Missense Mutation (SNP) | VAF 42/90 reads (47%) | SIFT tolerated (0.36); PolyPhen benign (0.066); catalogued as COSV99635128; called by muse, mutect2, varscan2
- LARP1B | c.317C>T p.A106V | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV99218861; called by muse, mutect2, varscan2
- LCA5 | c.1772G>A p.G591D | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT tolerated (0.5); PolyPhen benign (0.005); catalogued as COSV100878357; called by muse, mutect2, varscan2
- LCP1 | c.1858A>C p.M620L | Missense Mutation (SNP) | VAF 44/68 reads (65%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV100550058; called by muse, mutect2, varscan2
- LDB3 | c.1826T>A p.L609Q | Missense Mutation (SNP) | VAF 89/107 reads (83%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.579); catalogued as COSV99555839; called by muse, mutect2, varscan2
- LIMCH1 | c.641A>G p.Q214R | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as COSV100574330; called by muse, mutect2, varscan2
- LRRC37B | c.1967T>C p.L656S | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100496504; called by muse, mutect2, varscan2
- MAPK10 | c.647G>A p.G216E (on ENST00000359221 / NM_001351625.2; = p.G254E on NM_002753.5) | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV100175329; called by muse, mutect2, varscan2
- MAPK1IP1L | c.169G>T p.A57S | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.197); catalogued as COSV101133387; called by muse, mutect2, varscan2
- MDN1 | c.4192A>T p.T1398S | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.665); catalogued as COSV101021785; called by muse, mutect2, varscan2
- MEGF8 | c.5131C>T p.P1711S (on ENST00000251268 / NM_001271938.2; = p.P1644S on NM_001410.3) | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99238771; called by muse, mutect2, varscan2
- MEMO1 | c.853A>C p.S285R | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99704640; called by muse, mutect2, varscan2
- MSH4 | c.1045A>T p.R349* | Nonsense Mutation (SNP) | VAF 27/73 reads (37%) | catalogued as rs937592861, COSV99592449; called by muse, mutect2, varscan2
- MTMR14 | c.202G>C p.D68H | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56003135; called by muse, mutect2, varscan2
- MUC17 | c.5965A>G p.S1989G | Missense Mutation (SNP) | VAF 135/369 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.092); catalogued as COSV100074880, COSV60287538; called by muse, mutect2, varscan2
- MX1 | c.784G>T p.D262Y | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99912819; called by muse, mutect2, varscan2
- MYEF2 | c.1227G>T p.M409I | Missense Mutation (SNP) | VAF 23/201 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.019); catalogued as COSV99982072; called by muse, mutect2, varscan2
- MYH1 | c.3704T>C p.L1235P | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs188804570, COSV99876755; called by muse, mutect2, varscan2
- MYH8 | c.3022C>G p.Q1008E | Missense Mutation (SNP) | VAF 66/131 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.059); catalogued as COSV101238703; called by muse, mutect2, varscan2
- NEK5 | c.1916C>T p.P639L | Missense Mutation (SNP) | VAF 25/31 reads (81%) | SIFT tolerated (0.13); PolyPhen benign (0.01); catalogued as rs375739928; called by muse, mutect2, varscan2
- NEXN | c.1714G>C p.E572Q | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99629538; called by muse, mutect2, varscan2
- NIM1K | c.197C>G p.T66R | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.317); catalogued as COSV100390417; called by muse, mutect2, varscan2
- NMRK2 | c.513C>A p.D171E | Missense Mutation (SNP) | VAF 27/45 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as COSV99396502; called by muse, mutect2, varscan2
- NOTCH1 | c.289C>G p.L97V | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT tolerated (0.5); PolyPhen benign (0.056); catalogued as COSV99491396; called by muse, mutect2, varscan2
- NOTCH3 | c.2452G>T p.A818S | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV54627056, COSV99656317; called by muse, mutect2, varscan2
- NRCAM | c.1381A>G p.N461D (on ENST00000379028 / NM_001371124.1; = p.N455D on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.026); catalogued as rs1354070684, COSV100695383; called by muse, mutect2, varscan2
- NSD1 | c.3479G>A p.W1160* | Nonsense Mutation (SNP) | VAF 23/29 reads (79%) | catalogued as COSV100729761; called by muse, mutect2, varscan2
- NVL | c.2024C>G p.P675R | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1305744982, COSV99895074; called by muse, mutect2, varscan2
- NYAP1 | c.1867G>T p.G623C | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.824); catalogued as COSV100278663; called by muse, mutect2, varscan2
- OBSCN | c.781G>C p.V261L | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.999); catalogued as COSV99483740; called by muse, mutect2, varscan2
- ODAM | c.650C>T p.S217L | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV101258102; called by muse, mutect2
- OPRPN | c.726A>T p.K242N | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.948); catalogued as COSV101271105, COSV68192676; called by muse, mutect2, varscan2
- OR13C3 | c.36G>T p.L12F | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); catalogued as COSV101053355; called by muse, mutect2, varscan2
- OR1L4 | c.49G>T p.G17C | Missense Mutation (SNP) | VAF 64/228 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52340696; called by muse, mutect2, varscan2
- OR2F1 | c.733C>A p.L245I | Missense Mutation (SNP) | VAF 24/40 reads (60%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV101231332; called by muse, mutect2, varscan2
- OR4C12 | c.157C>A p.L53M | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.459); catalogued as COSV100078655, COSV58859325; called by muse, mutect2, varscan2
- OR4C3 | c.695G>T p.C232F | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as rs759470245, COSV100168250; called by muse, mutect2, varscan2
- OR4K13 | c.707C>T p.A236V | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV59860290; called by muse, mutect2, varscan2
- OR4X2 | c.148C>A p.P50T | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100183328; called by muse, mutect2, varscan2
- OR52I2 | c.559A>T p.T187S | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.151); catalogued as COSV100443009; called by muse, mutect2, varscan2
- OR5J2 | c.266A>T p.K89M | Missense Mutation (SNP) | VAF 39/98 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.45); catalogued as COSV100399219; called by muse, mutect2, varscan2
- OR7A5 | c.707A>C p.K236T | Missense Mutation (SNP) | VAF 40/92 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV100457926; called by muse, mutect2, varscan2
- OR8D4 | c.44C>T p.S15L | Missense Mutation (SNP) | VAF 36/64 reads (56%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV58431480; called by muse, mutect2, varscan2
- OR8H2 | c.367T>C p.Y123H | Missense Mutation (SNP) | VAF 54/181 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.98); catalogued as rs780133182, COSV100542468; called by muse, mutect2, varscan2
- PAPPA2 | c.3258G>A p.M1086I | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs773324580, COSV100868564; called by mutect2, varscan2
- PARP15 | c.1312C>A p.P438T (on ENST00000464300 / NM_001113523.3; = p.P204T on NM_152615.2) | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.48); PolyPhen benign (0.028); catalogued as COSV100117194; called by muse, mutect2, varscan2
- PCDH1 | c.833C>A p.P278H | Missense Mutation (SNP) | VAF 18/25 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99746885; called by muse, mutect2, varscan2
- PCDH15 | c.251G>T p.W84L | Missense Mutation (SNP) | VAF 49/100 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); catalogued as COSV100226824; called by muse, mutect2, varscan2
- PCDHA2 | c.1936C>T p.R646C | Missense Mutation (SNP) | VAF 34/47 reads (72%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.056); catalogued as rs1482463175, COSV100974129, COSV65365942; called by muse, mutect2, varscan2
- PCDHGA3 | c.1069C>T p.P357S | Missense Mutation (SNP) | VAF 29/39 reads (74%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.034); catalogued as rs749309525, COSV54010660, COSV54053962; called by muse, mutect2, varscan2
- PCK2 | c.1280C>T p.P427L | Missense Mutation (SNP) | VAF 21/135 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752400018, COSV53749659; called by muse, mutect2, varscan2
- PDE1C | c.740C>A p.T247K | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100373667; called by muse, mutect2, varscan2
- PIEZO2 | c.7071C>A p.D2357E | Missense Mutation (SNP) | VAF 40/70 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99555418; called by muse, mutect2, varscan2
- PLAAT1 | c.680T>C p.F227S (on ENST00000650797; = p.F122S on NM_020386.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99290957; called by muse, mutect2, varscan2
- PLEKHG1 | c.1514C>T p.P505L | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.056); catalogued as rs751987497, COSV100651855; called by muse, mutect2, varscan2
- PLXNA2 | c.4724A>G p.E1575G | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.096); catalogued as COSV100885811; called by muse, mutect2, varscan2
- PODN | c.407G>T p.R136L (on ENST00000395871; = p.R88L on NM_153703.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.343); catalogued as COSV57011422, COSV57014519; called by muse, mutect2, varscan2
- POLR1F | c.670A>G p.K224E | Missense Mutation (SNP) | VAF 60/156 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55997833, COSV99749043; called by muse, mutect2, varscan2
- PPFIA3 | c.1912del p.V638Cfs*90 | Frame Shift Del (DEL) | VAF 10/35 reads (29%) | catalogued as COSV100494912; called by mutect2, pindel, varscan2
- PPHLN1 | c.143G>C p.S48T | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT tolerated (0.06); PolyPhen benign (0.053); catalogued as COSV99872273; called by muse, mutect2, varscan2
- PPIL3 | c.123A>G p.I41M | Missense Mutation (SNP) | VAF 53/102 reads (52%) | SIFT tolerated (0.06); PolyPhen benign (0.219); catalogued as COSV99626962; called by muse, mutect2, varscan2
- PRAM1 | c.1318C>T p.R440W | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99725841; called by muse, mutect2, varscan2
- PRAME | c.860A>C p.Q287P | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101287224; called by muse, mutect2, varscan2
- PRAMEF14 | c.1370G>T p.C457F | Missense Mutation (SNP) | VAF 48/116 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs1389272298; called by muse, mutect2, varscan2
- PRB1 | c.309A>T p.Q103H | Missense Mutation (SNP) | VAF 68/863 reads (8%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.701); catalogued as COSV99556028; called by muse, mutect2
- PRKCB | c.940A>G p.T314A | Missense Mutation (SNP) | VAF 32/42 reads (76%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as rs1377518552, COSV100335234; called by muse, mutect2, varscan2
- PRKCI | c.236C>T p.T79I | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.053); catalogued as COSV99856125; called by muse, mutect2, varscan2
- PRKDC | c.2418A>T p.S806= | Splice Region (SNP) | VAF 14/36 reads (39%) | catalogued as COSV100042590, COSV58060164; called by muse, mutect2, varscan2
- PSG8 | c.476G>T p.R159M | Missense Mutation (SNP) | VAF 99/241 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.243); catalogued as COSV100126567; called by muse, mutect2, varscan2
- PTGES3L-AARSD1 | c.1282G>A p.A428T (on ENST00000421990 / NM_001136042.2; = p.A410T on NM_025267.3) | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV64184867; called by muse, mutect2, varscan2
- PTN | c.258G>T p.K86N | Missense Mutation (SNP) | VAF 27/41 reads (66%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.945); catalogued as COSV61967933; called by muse, mutect2, varscan2
- PTPN13 | c.6720G>C p.K2240N (on ENST00000411767 / NM_080683.3; = p.K2221N on NM_006264.3) | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100365367; called by muse, mutect2, varscan2
- PXDNL | c.851T>A p.V284E | Missense Mutation (SNP) | VAF 37/160 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.148); catalogued as COSV100686005, COSV62493459; called by muse, mutect2, varscan2
- R3HCC1L | c.1474A>G p.S492G | Missense Mutation (SNP) | VAF 46/60 reads (77%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV100107524; called by muse, mutect2, varscan2
- RAB3C | c.451C>T p.R151W | Missense Mutation (SNP) | VAF 27/32 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs895761649, COSV51435331; called by muse, mutect2, varscan2
- RAG2 | c.334A>G p.I112V | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs373703454; called by muse, mutect2, varscan2
- RANBP6 | c.1753G>C p.A585P | Missense Mutation (SNP) | VAF 69/107 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1297212650, COSV52391789, COSV99424375; called by muse, mutect2, varscan2
- RASGEF1B | c.778G>T p.E260* | Nonsense Mutation (SNP) | VAF 7/34 reads (21%) | catalogued as COSV100021129; called by muse, mutect2, varscan2
- REV3L | c.3890C>T p.S1297F | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.259); catalogued as COSV100725648; called by muse, mutect2, varscan2
- RIN3 | c.417G>C p.L139F | Missense Mutation (SNP) | VAF 43/160 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99379946; called by muse, mutect2, varscan2
- RNF111 | c.302G>T p.G101V | Missense Mutation (SNP) | VAF 32/47 reads (68%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100789170; called by muse, mutect2, varscan2
- RNF175 | c.328G>A p.G110R | Missense Mutation (SNP) | VAF 41/80 reads (51%) | SIFT tolerated (0.35); PolyPhen benign (0.171); catalogued as COSV99924277; called by muse, mutect2, varscan2
- RP1 | c.4114C>A p.L1372I | Missense Mutation (SNP) | VAF 41/81 reads (51%) | SIFT tolerated (0.07); PolyPhen benign (0.137); catalogued as COSV99608678; called by muse, mutect2, varscan2
- RPGRIP1 | c.2069T>A p.F690Y | Missense Mutation (SNP) | VAF 73/163 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs781576477, COSV99251741; called by muse, mutect2, varscan2
- RPS6KC1 | c.994A>T p.S332C | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100874073; called by muse, mutect2, varscan2
- RREB1 | c.1241C>T p.P414L | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.88); catalogued as COSV100619803; called by muse, mutect2, varscan2
- RTL4 | c.194A>G p.H65R | Missense Mutation (SNP) | VAF 28/38 reads (74%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as rs1219651373, COSV100466132; called by muse, mutect2, varscan2
- RYR2 | c.2087G>T p.G696V | Missense Mutation (SNP) | VAF 31/59 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63717567; called by muse, mutect2, varscan2
- SAR1A | c.482G>A p.G161E | Missense Mutation (SNP) | VAF 15/22 reads (68%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.721); catalogued as COSV100951706, COSV100951712; called by muse, mutect2, varscan2
- SBF1 | c.1608G>T p.R536S | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.121); catalogued as COSV100818003; called by muse, mutect2, varscan2
- SCN4A | c.2805G>C p.M935I | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV101438642; called by muse, mutect2, varscan2
- SCN7A | c.2063A>G p.E688G | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101313349; called by muse, mutect2, varscan2
- SCP2D1 | c.334G>T p.E112* | Nonsense Mutation (SNP) | VAF 10/40 reads (25%) | catalogued as COSV53857190, COSV99601912; called by muse, mutect2, varscan2
- SECISBP2L | c.3170A>C p.E1057A (on ENST00000559471 / NM_001193489.2; = p.E1012A on NM_014701.4) | Missense Mutation (SNP) | VAF 28/44 reads (64%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); catalogued as COSV99960919; called by muse, varscan2
- SERPINA6 | c.637C>A p.L213M | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.7); catalogued as COSV100448453; called by muse, mutect2, varscan2
- SH3PXD2A | c.2111C>G p.S704C (on ENST00000369774 / NM_001365079.1; = p.S676C on NM_014631.2) | Missense Mutation (SNP) | VAF 26/132 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.987); catalogued as rs754305451, COSV100280441; called by muse, mutect2, varscan2
- SLC26A5 | c.793G>T p.G265W | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100100071; called by muse, mutect2, varscan2
- SLC30A10 | c.761T>C p.V254A | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.61); catalogued as COSV100751589, COSV63071477; called by muse, mutect2, varscan2
- SLC35G3 | c.850G>A p.A284T | Missense Mutation (SNP) | VAF 65/155 reads (42%) | SIFT tolerated (0.55); PolyPhen benign (0.011); catalogued as rs748027779, COSV52012021; called by muse, mutect2, varscan2
- SLC35G3 | c.568G>C p.A190P | Missense Mutation (SNP) | VAF 64/188 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.157); catalogued as rs201078434, COSV52011209, COSV99269170; called by muse, varscan2
- SLC45A2 | c.538C>A p.L180I | Missense Mutation (SNP) | VAF 30/54 reads (56%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV99673084; called by muse, mutect2, varscan2
- SLIT2 | c.526G>T p.D176Y | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as COSV99886862; called by muse, mutect2, varscan2
- SLITRK2 | c.257C>A p.S86Y | Missense Mutation (SNP) | VAF 32/52 reads (62%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.824); catalogued as COSV100158137; called by muse, mutect2, varscan2
- SLITRK4 | c.1159A>T p.N387Y | Missense Mutation (SNP) | VAF 58/87 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100567495; called by muse, mutect2, varscan2
- SLITRK4 | c.409C>G p.Q137E | Missense Mutation (SNP) | VAF 53/68 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100567485, COSV100567496; called by muse, mutect2, varscan2
- SNAP91 | c.372A>G p.I124M | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99536409; called by muse, mutect2, varscan2
- SNTG1 | c.1319A>C p.K440T | Missense Mutation (SNP) | VAF 31/137 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs752964062, COSV99385826; called by muse, mutect2, varscan2
- SOX6 | c.961A>G p.S321G | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.52); PolyPhen benign (0.206); catalogued as COSV100323134; called by muse, mutect2, varscan2
- SPAG17 | c.2207T>C p.L736P | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.299); catalogued as rs1172291315, COSV100310369; called by muse, mutect2, varscan2
- SPATA31E1 | c.3006G>C p.E1002D | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0.112); catalogued as rs746898378, COSV100350997; called by muse, mutect2, varscan2
- SPATS1 | c.740C>T p.P247L | Missense Mutation (SNP) | VAF 34/71 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99913638; called by muse, mutect2, varscan2
- SPOPL | c.679G>T p.A227S | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); catalogued as COSV54513851, COSV99699752; called by muse, mutect2
- STAB2 | c.1829G>T p.S610I | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.599); catalogued as COSV101186268; called by muse, mutect2, varscan2
- STXBP5 | c.257G>A p.R86H | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs144000289; called by muse, mutect2, varscan2
- SYCP1 | c.439G>C p.A147P | Missense Mutation (SNP) | VAF 44/103 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101051174; called by muse, mutect2, varscan2
- SYCP2 | c.3434C>A p.S1145* | Nonsense Mutation (SNP) | VAF 10/31 reads (32%) | catalogued as COSV100698426; called by muse, mutect2, varscan2
- TACC2 | c.181G>T p.A61S | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV100553649; called by muse, mutect2, varscan2
- TAOK3 | c.142G>T p.E48* | Nonsense Mutation (SNP) | VAF 26/68 reads (38%) | catalogued as COSV100700388, COSV62401822; called by muse, mutect2, varscan2
- TCL1B | c.23G>T p.R8L | Missense Mutation (SNP) | VAF 20/139 reads (14%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as COSV100525781, COSV61552205; called by muse, mutect2, varscan2
- TEX13A | c.76G>T p.A26S | Missense Mutation (SNP) | VAF 19/28 reads (68%) | SIFT tolerated (0.14); PolyPhen benign (0.094); catalogued as COSV100781881; called by muse, mutect2, varscan2
- TG | c.3312C>A p.F1104L | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.695); catalogued as rs1430125983, COSV99600151, COSV99602940; called by muse, mutect2, varscan2
- THSD7A | c.2171G>T p.G724V | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.014); catalogued as rs1419882431; called by muse, mutect2
- TMEM74 | c.592G>C p.V198L | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.569); catalogued as COSV99865875; called by muse, mutect2, varscan2
- TNN | c.1690C>T p.R564C | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.77); catalogued as rs776425839, COSV53437237; called by mutect2, varscan2
- TNS2 | c.940G>T p.A314S (on ENST00000314250 / NM_170754.4; = p.A324S on NM_015319.2) | Missense Mutation (SNP) | VAF 84/204 reads (41%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.682); catalogued as COSV100048637; called by muse, mutect2, varscan2
- TNS3 | c.879G>T p.K293N | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as COSV100236302; called by muse, mutect2, varscan2
- TPR | c.5411C>T p.S1804L | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.091); catalogued as COSV100824239; called by muse, mutect2, varscan2
- TRIM38 | c.1283G>T p.G428V | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV100837636; called by muse, mutect2, varscan2
- TSPAN19 | c.729A>G p.I243M | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.059); catalogued as COSV101468114; called by muse, mutect2, varscan2
- TTC12 | c.1398A>T p.R466S | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as COSV100133322; called by muse, mutect2, varscan2
- TTN | c.60010C>A p.P20004T (on ENST00000591111; = p.P12580T on NM_003319.4) | Missense Mutation (SNP) | VAF 82/239 reads (34%) | PolyPhen possibly damaging (0.813); catalogued as COSV100627521; called by muse, mutect2, varscan2
- TTN | c.46303G>T p.G15435* (on ENST00000591111; = p.G8011* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 14/123 reads (11%) | catalogued as COSV100627524; called by muse, mutect2, varscan2
- TTN | c.3912G>T p.E1304D (on ENST00000591111; = p.E1258D on NM_003319.4) | Missense Mutation (SNP) | VAF 14/42 reads (33%) | PolyPhen benign (0.114); catalogued as COSV100627532; called by muse, mutect2, varscan2
- TUBG1 | c.1312G>A p.A438T | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99258896; called by muse, mutect2, varscan2
- TXNDC2 | c.835C>A p.P279T (on ENST00000306084 / NM_001098529.2; = p.P212T on NM_032243.6) | Missense Mutation (SNP) | VAF 47/199 reads (24%) | SIFT tolerated (0.58); PolyPhen benign (0.258); catalogued as COSV100046555; called by muse, mutect2, varscan2
- USP42 | c.1627A>G p.S543G | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs752695512, COSV100084856; called by muse, mutect2, varscan2
- USP6NL | c.944C>T p.S315F | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); catalogued as COSV99510090; called by muse, mutect2, varscan2
- UVRAG | c.1610T>A p.M537K | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated, low confidence (0.93); PolyPhen benign (0); catalogued as COSV100638599; called by muse, mutect2, varscan2
- VCAN | c.446-1G>A p.X149_splice | Splice Site (SNP) | VAF 24/39 reads (62%) | catalogued as COSV99427129; called by muse, mutect2, varscan2
- VPS13A | c.8231A>T p.D2744V | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100653410; called by muse, mutect2, varscan2
- XIRP2 | c.8513C>G p.T2838R (on ENST00000628543; = p.T3013R on NM_152381.6) | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.216); catalogued as COSV54684695, COSV99746800; called by muse, mutect2, varscan2
- ZMYND8 | c.215C>T p.P72L (on ENST00000311275 / NM_001363741.2; = p.P92L on NM_012408.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99521218; called by muse, mutect2, varscan2
- ZNF106 | c.1777G>C p.E593Q | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as COSV99783109; called by muse, mutect2
- ZNF292 | c.4579G>C p.V1527L | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); catalogued as COSV100371081; called by muse, mutect2, varscan2
- ZNF613 | c.1777G>C p.E593Q (on ENST00000293471 / NM_001031721.4; = p.E557Q on NM_024840.4) | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV53272260, COSV99523049; called by muse, mutect2
- ZNF684 | c.259G>C p.D87H | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.525); catalogued as COSV101016125; called by muse, mutect2
- ZNF836 | c.2071G>C p.E691Q | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.172); catalogued as COSV100441195; called by muse, mutect2, varscan2
- ZNF846 | c.1330C>T p.H444Y | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1054219480, COSV101194379, COSV67411793; called by muse, mutect2, varscan2
- ZNF93 | c.1302T>A p.F434L | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.414); catalogued as COSV100652413; called by muse, mutect2, varscan2
- ZSCAN5B | c.315G>C p.K105N | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.761); catalogued as COSV100748531; called by muse, mutect2, varscan2
- ANKRD20A4P | c.1869T>A p.S623R | Missense Mutation (SNP) | VAF 22/269 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.336); called by muse, mutect2
- ASXL3 | c.251A>T p.E84V | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- CYSLTR1 | c.220_221del p.C74Hfs*19 | Frame Shift Del (DEL) | VAF 18/36 reads (50%) | called by pindel, varscan2
- EIF2AK3 | c.3246del p.P1083Qfs*13 | Frame Shift Del (DEL) | VAF 53/144 reads (37%) | called by mutect2, pindel, varscan2
- EPHB4 | c.1906del p.A636Pfs*14 | Frame Shift Del (DEL) | VAF 42/138 reads (30%) | called by mutect2, pindel*, varscan2
- FAT2 | c.4874del p.P1625Hfs*4 | Frame Shift Del (DEL) | VAF 17/35 reads (49%) | called by mutect2, pindel, varscan2
- HNF1B | c.1008C>A p.H336Q | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.43); PolyPhen benign (0.012); called by muse, mutect2
- HNF4G | c.242-2A>G p.X81_splice (on ENST00000354370 / NM_001330561.2; = p.X128_splice on NM_004133.5) | Splice Site (SNP) | VAF 22/57 reads (39%) | called by mutect2, varscan2
- MAGEB6B | c.439G>T p.E147* | Nonsense Mutation (SNP) | VAF 32/58 reads (55%) | called by muse, mutect2, varscan2
- NAE1 | c.1495+1del p.X499_splice | Splice Site (DEL) | VAF 8/21 reads (38%) | called by mutect2, pindel, varscan2
- NEK11 | c.161del p.G54Efs*4 | Frame Shift Del (DEL) | VAF 20/45 reads (44%) | called by mutect2, pindel, varscan2
- PACRGL | c.313del p.E105Nfs*16 | Frame Shift Del (DEL) | VAF 13/37 reads (35%) | called by mutect2, pindel, varscan2
- PRAMEF19 | c.442A>T p.K148* | Nonsense Mutation (SNP) | VAF 68/295 reads (23%) | called by muse, varscan2
- PTPDC1 | c.1920_1929del p.S641Gfs*7 (on ENST00000375360 / NM_177995.3; = p.S693Gfs*7 on NM_152422.4) | Frame Shift Del (DEL) | VAF 19/152 reads (13%) | called by mutect2, pindel
- SERHL | n.125G>A | Splice Region (SNP) | VAF 10/35 reads (29%) | called by muse, mutect2, varscan2
- SPATA31A3 | c.1889C>A p.S630* | Nonsense Mutation (SNP) | VAF 37/62 reads (60%) | called by muse, mutect2, varscan2
- SPTA1 | c.3071del p.G1024Afs*87 | Frame Shift Del (DEL) | VAF 19/59 reads (32%) | called by mutect2, pindel, varscan2
- TNXB | c.4562dup p.D1522Rfs*37 (on ENST00000647633; = p.D1275Rfs*37 on NM_019105.8 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 6/14 reads (43%) | called by mutect2, varscan2
- AC109583.1 | c.906G>A p.R302= | Silent (SNP) | VAF 45/69 reads (65%) | catalogued as COSV100167911; called by muse, mutect2, varscan2
- ADAD2 | c.945C>T p.S315= (on ENST00000315906 / NM_001145400.2; = p.S397= on NM_139174.4) | Silent (SNP) | VAF 10/51 reads (20%) | catalogued as rs1316513805, COSV99235117; called by muse, mutect2, varscan2
- ADAM7 | c.732G>T p.V244= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as COSV99444925; called by muse, mutect2
- ADCY8 | c.2353C>A p.R785= | Silent (SNP) | VAF 22/65 reads (34%) | catalogued as COSV53933309, COSV99654063; called by muse, mutect2, varscan2
- AFF3 | c.2238C>T p.V746= | Silent (SNP) | VAF 28/68 reads (41%) | catalogued as COSV100419956; called by muse, mutect2
- AGAP2 | c.918C>T p.T306= | Silent (SNP) | VAF 29/62 reads (47%) | catalogued as COSV99224157; called by muse, mutect2, varscan2
- APBB1IP | c.297A>G p.L99= | Silent (SNP) | VAF 17/75 reads (23%) | catalogued as COSV100774453; called by muse, mutect2, varscan2
- APOA4 | c.747C>T p.A249= | Silent (SNP) | VAF 29/69 reads (42%) | catalogued as rs558924435, COSV100759391; called by muse, mutect2, varscan2
- ATF7IP | c.3447G>A p.Q1149= | Silent (SNP) | VAF 13/47 reads (28%) | catalogued as COSV99661244, COSV99662076; called by muse, mutect2, varscan2
- BRD9 | c.1473G>A p.S491= | Silent (SNP) | VAF 10/66 reads (15%) | catalogued as rs746068151, COSV100057554; called by mutect2, varscan2
- BRINP1 | c.576C>A p.I192= | Silent (SNP) | VAF 50/98 reads (51%) | catalogued as COSV99776767; called by muse, varscan2
- BRINP3 | c.1308C>G p.T436= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as COSV100819285, COSV66536526; called by muse, mutect2, varscan2
- C1orf112 | c.1140C>G p.L380= | Silent (SNP) | VAF 4/29 reads (14%) | catalogued as COSV53680607, COSV99610142; called by muse, mutect2
- CCT8L2 | c.12A>T p.T4= | Silent (SNP) | VAF 21/45 reads (47%) | catalogued as COSV100743069; called by muse, mutect2, varscan2
- CDT1 | c.1563C>G p.V521= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as COSV99967362; called by muse, mutect2, varscan2
- CFHR5 | c.636T>C p.P212= | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as COSV99889610; called by muse, mutect2, varscan2
- CFP | c.861T>C p.P287= | Silent (SNP) | VAF 9/13 reads (69%) | catalogued as COSV99901646; called by muse, mutect2, varscan2
- CHST2 | c.1311G>C p.R437= | Silent (SNP) | VAF 16/43 reads (37%) | catalogued as COSV100536115; called by muse, mutect2, varscan2
- COL3A1 | c.768A>T p.I256= | Silent (SNP) | VAF 13/24 reads (54%) | catalogued as COSV100483654, COSV58589069; called by muse, mutect2, varscan2
- COL5A1 | c.306C>A p.I102= | Silent (SNP) | VAF 19/90 reads (21%) | catalogued as COSV100880529; called by muse, mutect2, varscan2
- CR2 | c.2925T>A p.P975= | Silent (SNP) | VAF 14/33 reads (42%) | catalogued as COSV100889701; called by muse, mutect2, varscan2
- CSMD3 | c.2904C>A p.T968= (on ENST00000297405 / NM_001363185.1; = p.T864= on NM_052900.3) | Silent (SNP) | VAF 14/60 reads (23%) | catalogued as COSV99846171; called by muse, mutect2, varscan2
- DNAAF1 | c.1245C>A p.T415= | Silent (SNP) | VAF 35/89 reads (39%) | catalogued as rs147804813, COSV100533819; called by muse, mutect2, varscan2
- DNAH11 | c.2976A>C p.T992= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as COSV100180588; called by muse, mutect2, varscan2
- DNAH9 | c.7671G>A p.T2557= | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as rs143485595; called by muse, mutect2, varscan2
- DPY19L1 | c.741C>A p.S247= | Silent (SNP) | VAF 20/44 reads (45%) | catalogued as COSV100204957; called by muse, mutect2, varscan2
- EFCAB3 | c.1098T>C p.S366= | Silent (SNP) | VAF 29/71 reads (41%) | catalogued as COSV100540466; called by muse, mutect2, varscan2
- EGR2 | c.594C>T p.S198= | Silent (SNP) | VAF 68/81 reads (84%) | catalogued as COSV99654277; called by muse, mutect2, varscan2
- ENAM | c.2208T>C p.T736= | Silent (SNP) | VAF 18/73 reads (25%) | catalogued as COSV101253309; called by muse, mutect2, varscan2
- EXO5 | c.96A>G p.E32= | Silent (SNP) | VAF 37/78 reads (47%) | catalogued as COSV99591414; called by muse, mutect2, varscan2
- FAM160A2 | c.930A>T p.V310= | Silent (SNP) | VAF 55/163 reads (34%) | catalogued as COSV99792469; called by muse, mutect2, varscan2
- FANCB | c.378A>T p.L126= | Silent (SNP) | VAF 9/15 reads (60%) | catalogued as COSV100146674; called by muse, mutect2, varscan2
- FMOD | c.600G>A p.E200= | Silent (SNP) | VAF 33/130 reads (25%) | catalogued as COSV100724623; called by muse, mutect2, varscan2
- GATD1 | c.288G>T p.G96= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as COSV100168763; called by muse, mutect2, varscan2
- GEN1 | c.1806A>G p.Q602= | Silent (SNP) | VAF 18/53 reads (34%) | catalogued as COSV100438180; called by muse, mutect2, varscan2
- GRSF1 | c.1338C>T p.H446= | Silent (SNP) | VAF 11/23 reads (48%) | catalogued as COSV99636033; called by muse, mutect2, varscan2
- HSPA4 | c.780C>T p.I260= | Silent (SNP) | VAF 24/43 reads (56%) | catalogued as COSV59183526; called by muse, mutect2, varscan2
- IFI30 | c.330T>C p.S110= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as COSV99717685; called by muse, mutect2, varscan2
- IGF2R | c.5898A>G p.P1966= | Silent (SNP) | VAF 46/118 reads (39%) | catalogued as rs1289440559, COSV100808090; called by muse, mutect2, varscan2
- IGHD5-24 | c.6G>A p.E2= | Silent (SNP) | VAF 21/73 reads (29%) | catalogued as rs538893552; called by muse, mutect2, varscan2
- IRF2BP1 | c.42G>T p.L14= | Silent (SNP) | VAF 3/31 reads (10%) | catalogued as rs902626116, COSV100138994; called by muse, mutect2
- KCNB2 | c.6A>T p.A2= | Silent (SNP) | VAF 30/133 reads (23%) | catalogued as COSV101578988; called by muse, mutect2, varscan2
- KCNK2 | c.765C>T p.D255= (on ENST00000444842 / NM_001017425.3; = p.D240= on NM_014217.4) | Silent (SNP) | VAF 23/74 reads (31%) | catalogued as rs371463693, COSV101222318; called by muse, mutect2, varscan2
- KCNV1 | c.960G>T p.L320= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as rs1257336369, COSV99819371; called by muse, mutect2, varscan2
- KIF27 | c.1020C>T p.N340= | Silent (SNP) | VAF 29/102 reads (28%) | catalogued as COSV99927261; called by muse, mutect2, varscan2
- LRIF1 | c.1656A>G p.K552= | Silent (SNP) | VAF 11/30 reads (37%) | catalogued as COSV100870914; called by muse, mutect2, varscan2
- MTCL1 | c.5400A>T p.P1800= (on ENST00000306329 / NM_001378206.1; = p.P1481= on NM_015210.4) | Silent (SNP) | VAF 37/53 reads (70%) | catalogued as rs749719056, COSV100095465; called by muse, mutect2, varscan2
- NCAPD3 | c.1839C>T p.C613= | Silent (SNP) | VAF 28/66 reads (42%) | catalogued as rs753509301, COSV101599400; called by muse, mutect2, varscan2
- NCKAP5L | c.2148G>C p.L716= | Silent (SNP) | VAF 7/10 reads (70%) | catalogued as COSV100259169; called by muse, mutect2, varscan2
- NFATC2 | c.1266C>T p.A422= | Silent (SNP) | VAF 13/44 reads (30%) | catalogued as COSV101044628; called by muse, mutect2, varscan2
- NOTCH3 | c.2451C>T p.P817= | Silent (SNP) | VAF 16/60 reads (27%) | catalogued as rs757662917, COSV54636814; called by muse, mutect2, varscan2
- NPAP1 | c.3372G>C p.L1124= | Silent (SNP) | VAF 15/101 reads (15%) | catalogued as COSV100276098; called by muse, mutect2, varscan2
- NRDC | c.543A>G p.E181= | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as COSV100703799; called by muse, mutect2, varscan2
- OBSCN | c.23906G>A p.*7969= | Silent (SNP) | VAF 15/24 reads (63%) | catalogued as COSV100805396; called by muse, mutect2, varscan2
- OR13J1 | c.843C>A p.V281= | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as COSV100940836; called by muse, mutect2, varscan2
- OR2T1 | c.819C>T p.L273= | Silent (SNP) | VAF 40/134 reads (30%) | catalogued as rs762761236, COSV100822349; called by muse, mutect2, varscan2
- OR2T10 | c.756T>C p.Y252= | Silent (SNP) | VAF 14/24 reads (58%) | catalogued as rs758843051, COSV100393598; called by muse, mutect2, varscan2
- OR4C13 | c.708T>A p.S236= | Silent (SNP) | VAF 48/112 reads (43%) | catalogued as COSV101634232, COSV73648884; called by muse, mutect2, varscan2
- OR52N1 | c.654C>T p.I218= | Silent (SNP) | VAF 18/46 reads (39%) | catalogued as COSV57693090; called by muse, mutect2, varscan2
- OR56A4 | c.933G>T p.L311= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as rs537464742, COSV100417678; called by muse, mutect2, varscan2
- OR5F1 | c.474C>G p.V158= | Silent (SNP) | VAF 23/60 reads (38%) | catalogued as COSV99558895; called by muse, mutect2, varscan2
- PKD1L1 | c.1584T>A p.A528= | Silent (SNP) | VAF 33/83 reads (40%) | catalogued as COSV99221233; called by muse, mutect2, varscan2
- PKHD1 | c.5142C>T p.Y1714= | Silent (SNP) | VAF 25/51 reads (49%) | catalogued as COSV100584414; called by muse, mutect2, varscan2
- PKHD1L1 | c.11341C>A p.R3781= | Silent (SNP) | VAF 25/186 reads (13%) | catalogued as rs780025206, COSV101005949, COSV65745310; called by muse, mutect2, varscan2
- POC1B | c.1197A>G p.P399= | Silent (SNP) | VAF 45/103 reads (44%) | catalogued as COSV100544483; called by muse, mutect2, varscan2
- PRDM9 | c.208C>A p.R70= | Silent (SNP) | VAF 36/62 reads (58%) | catalogued as COSV57007053, COSV57007170; called by muse, mutect2, varscan2
- PROKR2 | c.279C>A p.A93= | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as COSV54086423, COSV99450604; called by muse, mutect2, varscan2
- PRR22 | c.1080G>C p.A360= | Silent (SNP) | VAF 32/76 reads (42%) | catalogued as COSV100288436; called by muse, mutect2, varscan2
- PTPN3 | c.1323C>T p.S441= | Silent (SNP) | VAF 34/101 reads (34%) | catalogued as rs199620488, COSV99356184; called by muse, mutect2, varscan2
- PTPRT | c.873C>A p.P291= | Silent (SNP) | VAF 11/26 reads (42%) | catalogued as rs758960459, COSV100625937; called by muse, mutect2, varscan2
- RASSF4 | c.126G>T p.L42= | Silent (SNP) | VAF 16/17 reads (94%) | catalogued as COSV100024490, COSV53574417; called by muse, mutect2, varscan2
- RDX | c.1548C>G p.T516= | Silent (SNP) | VAF 61/157 reads (39%) | catalogued as COSV100563058, COSV58193389; called by muse, mutect2, varscan2
- RNF183 | c.402G>T p.T134= | Silent (SNP) | VAF 38/70 reads (54%) | catalogued as rs769117547, COSV99938135; called by muse, mutect2, varscan2
- SCN10A | c.651C>T p.F217= | Silent (SNP) | VAF 31/53 reads (58%) | catalogued as rs1476063521, COSV101479514, COSV71860087; called by muse, mutect2, varscan2
- SEMA3E | c.2301C>T p.R767= | Silent (SNP) | VAF 60/162 reads (37%) | catalogued as rs758239590, COSV100319492; called by muse, mutect2, varscan2
- SLC16A1 | c.612G>A p.K204= | Silent (SNP) | VAF 16/47 reads (34%) | catalogued as rs763951746, COSV100856048; called by muse, mutect2, varscan2
- SLC18A3 | c.843C>A p.P281= | Silent (SNP) | VAF 29/39 reads (74%) | catalogued as COSV100340805; called by muse, mutect2, varscan2
- SLC1A6 | c.861C>T p.H287= | Silent (SNP) | VAF 35/104 reads (34%) | catalogued as COSV55667941; called by muse, mutect2, varscan2
- SLC35F1 | c.321C>G p.V107= | Silent (SNP) | VAF 41/117 reads (35%) | catalogued as COSV100838096; called by muse, mutect2, varscan2
- SLC41A1 | c.267C>T p.S89= | Silent (SNP) | VAF 29/72 reads (40%) | catalogued as COSV100900484; called by muse, mutect2, varscan2
- SMC3 | c.3072G>T p.R1024= | Silent (SNP) | VAF 50/68 reads (74%) | catalogued as rs748366020, COSV100700034; called by muse, mutect2, varscan2
- SNAPC4 | c.3663G>T p.T1221= | Silent (SNP) | VAF 7/14 reads (50%) | catalogued as COSV100047655; called by muse, mutect2, varscan2
- SNTB1 | c.738C>G p.L246= | Silent (SNP) | VAF 10/83 reads (12%) | catalogued as COSV101180108; called by muse, mutect2, varscan2
- STAT4 | c.651C>A p.T217= | Silent (SNP) | VAF 62/159 reads (39%) | catalogued as COSV100636175; called by muse, mutect2, varscan2
- SYNE1 | c.24843C>T p.I8281= (on ENST00000367255 / NM_182961.4; = p.I8210= on NM_033071.3) | Silent (SNP) | VAF 20/46 reads (43%) | catalogued as COSV54962397; called by muse, mutect2, varscan2
- SYT11 | c.255T>G p.P85= | Silent (SNP) | VAF 38/91 reads (42%) | catalogued as COSV100851344; called by muse, mutect2, varscan2
- SYTL2 | c.2376A>G p.G792= (on ENST00000528231 / NM_001162951.2; = p.G768= on NM_032943.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 26/73 reads (36%) | catalogued as COSV100314867; called by muse, mutect2, varscan2
- TRIM38 | c.1131G>A p.E377= | Silent (SNP) | VAF 33/80 reads (41%) | catalogued as rs199895933, COSV100837635; called by muse, mutect2, varscan2
- TRMT61B | c.405A>G p.E135= | Silent (SNP) | VAF 16/38 reads (42%) | catalogued as rs538894898, COSV100066786; called by muse, mutect2, varscan2
- TRPM3 | c.4206G>T p.S1402= (on ENST00000357533 / NM_001366142.2; = p.S1257= on NM_020952.6) | Silent (SNP) | VAF 33/79 reads (42%) | catalogued as COSV100678588, COSV62587315; called by muse, mutect2, varscan2
- TTN | c.34152T>A p.T11384= (on ENST00000591111; = p.T10457= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as COSV100627529; called by muse, mutect2, varscan2
- TUBG1 | c.1311G>T p.A437= | Silent (SNP) | VAF 23/84 reads (27%) | catalogued as COSV99258893; called by muse, mutect2, varscan2
- VARS1 | c.2964C>T p.R988= | Silent (SNP) | VAF 27/69 reads (39%) | catalogued as COSV100791853; called by muse, mutect2, varscan2
- VTA1 | c.873T>A p.A291= | Silent (SNP) | VAF 21/58 reads (36%) | catalogued as COSV100859260; called by muse, mutect2, varscan2
- ZAP70 | c.462T>A p.A154= | Silent (SNP) | VAF 24/53 reads (45%) | catalogued as COSV99385897; called by muse, mutect2, varscan2
- ZBTB4 | c.75C>A p.L25= | Silent (SNP) | VAF 8/9 reads (89%) | catalogued as COSV100263721; called by muse, mutect2, varscan2
- ZFHX4 | c.18C>G p.S6= | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as COSV99266884; called by muse, mutect2, varscan2
- ZFHX4 | c.2079G>C p.T693= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as COSV50650428, COSV99266889; called by muse, mutect2, varscan2
- ZNF100 | c.900G>A p.R300= | Silent (SNP) | VAF 33/78 reads (42%) | catalogued as COSV99974308; called by muse, mutect2, varscan2
- ZNF675 | c.1428A>T p.G476= | Silent (SNP) | VAF 14/40 reads (35%) | catalogued as COSV100705180; called by muse, mutect2, varscan2
- ZNF827 | c.1287G>T p.R429= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as COSV101061708; called by muse, mutect2, varscan2
- AGAP7P | n.1115G>C | RNA (SNP) | VAF 27/137 reads (20%) | catalogued as rs1554941195; called by muse, mutect2, varscan2
- AQP1 | c.*327G>T | 3'UTR (SNP) | VAF 5/9 reads (56%) | catalogued as rs773654140, COSV100311035, COSV61268552; called by muse, mutect2, varscan2
- CHCHD2P9 | n.355A>G | RNA (SNP) | VAF 26/54 reads (48%) | called by muse, mutect2, varscan2
- GH2 | c.457-123C>G | Intron (SNP) | VAF 94/156 reads (60%) | catalogued as rs750979087, COSV100237115, COSV60427867; called by muse, mutect2, varscan2
- KRT18P23 | chr22:44570517 G>C | 3'Flank (SNP) | VAF 5/17 reads (29%) | called by muse, mutect2
- NBPF11 | c.-548-3176C>T | Intron (SNP) | VAF 23/43 reads (53%) | called by muse, mutect2, varscan2
- OSGIN1 | n.425G>A | RNA (SNP) | VAF 24/65 reads (37%) | catalogued as COSV100652451; called by muse, mutect2
